Somatic mutation profile of tumor specimen HTMCP-03-06-02387-01A (aliquot HTMCP-03-06-02387-01A-01D-10409) from CGCI case HTMCP-03-06-02387, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIA; Tumor grade: G3.
Specimen HTMCP-03-06-02387-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd86bac5-0a36-4410-b415-9a77d11b831d.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02387-10A (Blood Derived Normal), aliquot HTMCP-03-06-02387-10A-01D-10409; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d24a689b-1cba-4c83-be91-dced41c95fe1

The open-access MAF lists 44 somatic variants for this specimen: 35 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 7, Nonsense Mutation 3, Frame Shift Del 1, Splice Site 1, Splice Region 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 53/90 reads (59%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AHI1 | c.2440C>T p.R814C | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.173); catalogued as rs1363664911, COSV55630203; called by muse, mutect2, varscan2
- AHNAK2 | c.9524C>T p.A3175V | Missense Mutation (SNP) | VAF 97/258 reads (38%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.914); catalogued as rs983833318; called by muse, mutect2, varscan2
- COL16A1 | c.2641C>T p.Q881* | Nonsense Mutation (SNP) | VAF 18/58 reads (31%) | catalogued as rs1418532602; called by muse, mutect2, varscan2
- COL7A1 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as rs145343367; called by muse, mutect2, varscan2
- DNAH14 | c.4774G>T p.D1592Y (on ENST00000445597; = p.D1997Y on NM_001367479.1) | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70532455; called by muse, mutect2, varscan2
- GRM3 | c.2167C>T p.R723W | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs560446375, COSV64469346; called by muse, mutect2, varscan2
- IQCH | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 59/362 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as rs1419331570; called by muse, mutect2, varscan2
- KIAA0100 | c.2846G>A p.R949H | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101197178; called by muse, mutect2, varscan2
- MOV10 | c.2165C>T p.P722L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as rs763080177; called by muse, mutect2, varscan2
- MTTP | c.1804G>A p.A602T | Missense Mutation (SNP) | VAF 55/167 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1052964561, COSV55503541, COSV55509361; called by muse, mutect2, varscan2
- MYH7 | c.1874C>T p.A625V | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.2); catalogued as rs730880932; ClinVar: uncertain significance; called by mutect2, varscan2
- NAV3 | c.5935G>A p.D1979N (on ENST00000397909 / NM_001024383.2; = p.D1957N on NM_014903.6) | Missense Mutation (SNP) | VAF 49/174 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99894751; called by muse, mutect2, varscan2
- NOS2 | c.1954C>T p.Q652* | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as rs756812497, COSV58227420; called by muse, mutect2, varscan2
- PCDH15 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as rs749305630, COSV57257918; called by muse, mutect2, varscan2
- PLCG2 | c.1873G>A p.A625T | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as rs1009796025, COSV63876708; called by muse, mutect2, varscan2
- PLEKHM1 | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749275402; called by muse, mutect2, varscan2
- RASGRP2 | c.949G>C p.A317P | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62450160; called by muse, mutect2, varscan2
- RFPL2 | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as rs755080826, COSV99964084, COSV99964676; called by muse, mutect2, varscan2
- SCN5A | c.3840C>T p.D1280= (on ENST00000333535 / NM_198056.3; = p.D1279= on NM_000335.5) | Splice Region (SNP) | VAF 30/87 reads (34%) | catalogued as rs749069817, COSV61129635; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- SF3B1 | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.427); catalogued as rs1421809024; called by muse, mutect2, varscan2
- SV2A | c.560G>T p.G187V | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64964478; called by muse, mutect2, varscan2
- WFIKKN2 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.243); catalogued as rs777694304; called by muse, mutect2, varscan2
- ZNF469 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1009769670; ClinVar: uncertain significance; called by muse, mutect2
- AGBL5 | c.215+1G>A p.X72_splice | Splice Site (SNP) | VAF 14/134 reads (10%) | called by muse, mutect2
- ANKRD30BL | c.191A>G p.D64G | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.401); called by muse, mutect2
- CADPS | c.1768C>T p.R590* | Nonsense Mutation (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- CLCNKB | c.217_218del p.S73Cfs*119 | Frame Shift Del (DEL) | VAF 10/41 reads (24%) | called by pindel, varscan2
- COBL | c.2695A>G p.K899E | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- DMD | c.5720G>C p.R1907T | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- MUC5B | c.14315T>A p.M4772K | Missense Mutation (SNP) | VAF 62/192 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRSS3 | c.225G>C p.M75I (on ENST00000361005 / NM_007343.4; = p.M183I on NM_002771.3) | Missense Mutation (SNP) | VAF 168/388 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); called by muse, varscan2
- RAPGEF1 | c.3058G>A p.D1020N | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- RYR2 | c.12349A>G p.T4117A | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- ZSWIM6 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- EDC4 | c.369C>T p.V123= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as rs749190020, COSV54646877; called by muse, mutect2, varscan2
- EFTUD2 | c.1236C>T p.I412= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as rs943395939; called by muse, mutect2, varscan2
- FAM47B | c.972C>T p.P324= | Silent (SNP) | VAF 127/239 reads (53%) | catalogued as rs1485527852, COSV100264573; called by muse, mutect2, varscan2
- SLITRK2 | c.261C>T p.N87= | Silent (SNP) | VAF 53/192 reads (28%) | catalogued as COSV100157381; called by muse, mutect2, varscan2
- TAF1 | c.2403G>A p.R801= (on ENST00000373790 / NM_138923.4; = p.R822= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/145 reads (23%) | called by muse, mutect2, varscan2
- ZFHX3 | c.3441G>A p.T1147= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs758475144; called by muse, mutect2, varscan2
- ZNF729 | c.3360G>A p.T1120= | Silent (SNP) | VAF 76/205 reads (37%) | catalogued as rs879089251, COSV62605773; called by muse, mutect2, varscan2
- DNAI2 | c.-6G>A | 5'UTR (SNP) | VAF 32/101 reads (32%) | catalogued as rs769602136, COSV56762214; called by muse, mutect2, varscan2
- ZFP28 | c.898+155C>A | Intron (SNP) | VAF 58/112 reads (52%) | catalogued as rs775986168; called by muse, mutect2, varscan2
